Somatic mutation profile of tumor specimen C3L-08279-02 (aliquot CPT0477910010) from CPTAC case C3L-08279, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 73.7 years (26,924 days).
Specimen C3L-08279-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecebba0a-5e4a-422a-9eea-8318e8e5fe8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08279-31 (Blood Derived Normal), aliquot CPT0475750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7b828f5-eda3-45ad-8d98-6574ef152f45

The open-access MAF lists 40 somatic variants for this specimen: 27 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 26, Silent 13, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD62 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 79/479 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as rs192488571; called by muse, mutect2, varscan2
- FAT4 | c.4346C>A p.A1449E | Missense Mutation (SNP) | VAF 18/511 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as COSV67891290; called by muse, mutect2
- GTF2H4 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 31/372 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760294963; called by muse, mutect2
- KLHDC7A | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 48/568 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs753880629, COSV101272758, COSV68769381; called by muse, mutect2
- KPNA1 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 17/290 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as rs1443873785; called by muse, mutect2
- KRT10 | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 21/287 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV54089119; called by muse, mutect2
- MYH3 | c.4913C>T p.A1638V | Missense Mutation (SNP) | VAF 30/343 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.783); catalogued as rs1316332773; called by muse, mutect2
- PLCH2 | c.2534G>A p.R845H | Missense Mutation (SNP) | VAF 44/522 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753409388, COSV53939576; called by muse, mutect2
- PPP1R18 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 54/658 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); catalogued as rs1278714515; called by muse, mutect2
- RD3 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 81/551 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.057); catalogued as rs778700426, COSV65362777; called by muse, mutect2, varscan2
- SP2 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 12/299 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1042801367; called by muse, mutect2
- TBX18 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1173360363; called by muse, mutect2
- TCF4 | c.899C>A p.A300D | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV61891532; called by muse, mutect2
- TLE4 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 14/308 reads (5%) | catalogued as COSV54634491; called by muse, mutect2
- TMEM132D | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 23/375 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1406077872, COSV70602486; called by muse, mutect2
- TRPM3 | c.4388T>C p.I1463T (on ENST00000357533 / NM_001366142.2; = p.I1318T on NM_020952.6) | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs776544359; called by muse, mutect2
- TTN | c.61462C>T p.R20488C (on ENST00000591111; = p.R13064C on NM_003319.4) | Missense Mutation (SNP) | VAF 16/320 reads (5%) | PolyPhen probably damaging (0.998); catalogued as rs763729258, COSV60276537, COSV60403449; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- UGT1A9 | c.394A>G p.K132E | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.123); catalogued as COSV60848609; called by muse, mutect2
- AC245033.1 | c.1610T>C p.V537A | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); called by muse, mutect2
- ADGRG1 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- ATOH7 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 20/397 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.945); called by muse, mutect2
- C19orf85 | c.383T>A p.L128H | Missense Mutation (SNP) | VAF 32/482 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- CYGB | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 13/436 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2
- KBTBD12 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MUC5B | c.17007C>G p.H5669Q | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2
- TMEM200C | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 18/399 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- ZNF582 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- ADO | c.669C>T p.Y223= | Silent (SNP) | VAF 18/526 reads (3%) | called by muse, mutect2
- DDX21 | c.1713A>T p.I571= | Silent (SNP) | VAF 10/287 reads (3%) | called by muse, mutect2
- DDX46 | c.2007C>A p.T669= | Silent (SNP) | VAF 32/326 reads (10%) | called by muse, mutect2
- FAT3 | c.12639C>T p.R4213= | Silent (SNP) | VAF 21/548 reads (4%) | catalogued as COSV53078901; called by muse, mutect2
- GABRG3 | c.423T>A p.A141= | Silent (SNP) | VAF 15/389 reads (4%) | called by muse, mutect2
- LRFN5 | c.1878C>T p.T626= | Silent (SNP) | VAF 32/372 reads (9%) | catalogued as rs1396754459, COSV53265957, COSV53276475; called by muse, mutect2
- MAOA | c.1224G>C p.T408= | Silent (SNP) | VAF 15/398 reads (4%) | called by muse, mutect2
- OR2A12 | c.282T>C p.A94= | Silent (SNP) | VAF 22/326 reads (7%) | called by muse, mutect2
- PDE8B | c.633C>T p.L211= | Silent (SNP) | VAF 18/306 reads (6%) | catalogued as rs1222916567; called by muse, mutect2
- PLIN3 | c.147C>G p.T49= | Silent (SNP) | VAF 18/392 reads (5%) | called by muse, mutect2
- PRND | c.435C>T p.C145= | Silent (SNP) | VAF 30/462 reads (6%) | catalogued as rs779451602, COSV59896285, COSV59896493; called by muse, mutect2
- PTGFRN | c.2448C>T p.P816= | Silent (SNP) | VAF 16/290 reads (6%) | catalogued as rs1305304723; called by muse, mutect2
- TPO | c.969C>T p.F323= | Silent (SNP) | VAF 26/727 reads (4%) | catalogued as COSV61112567; called by muse, mutect2
